Somatic mutation profile of tumor specimen TCGA-EY-A2OO-01A (aliquot TCGA-EY-A2OO-01A-11D-A19Y-09) from TCGA case TCGA-EY-A2OO, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IB; Tumor grade: G3; Age at diagnosis: 56.9 years (20,797 days).
Specimen TCGA-EY-A2OO-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) eb4dec84-81e0-4011-bad5-be3f554e2efb.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-EY-A2OO-10A (Blood Derived Normal), aliquot TCGA-EY-A2OO-10A-01D-A19Y-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7ef3ca89-9761-4272-8ca2-09dd62827f7e

The open-access MAF lists 64 somatic variants for this specimen: 53 protein-altering or splice-affecting, 8 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 40, Silent 8, Nonsense Mutation 7, Intron 3, Frame Shift Del 3, In Frame Del 2, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.34G>A p.G12S | Missense Mutation (SNP) | VAF 45/54 reads (83%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen possibly damaging (0.582); catalogued as rs121913530, CM076251, COSV55497461, COSV55497469, COSV55497582, COSV56157736; ClinVar: not provided / pathogenic; called by muse, mutect2, varscan2
- PPP2R1A | c.547C>T p.R183W | Missense Mutation (SNP) | VAF 35/62 reads (56%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1057519946, COSV59042187, COSV59042498; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ABCA13 | c.12472C>T p.L4158F | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); catalogued as rs1378893581, COSV101446972; called by muse, mutect2, varscan2
- AC013489.1 | c.953G>A p.R318H | Missense Mutation (SNP) | VAF 19/48 reads (40%) | SIFT tolerated (0.14); PolyPhen benign (0.028); catalogued as rs746255778, COSV99183866; called by muse, mutect2, varscan2
- ALPI | c.1360G>A p.E454K | Missense Mutation (SNP) | VAF 17/33 reads (52%) | SIFT deleterious (0); PolyPhen possibly damaging (0.553); catalogued as COSV55014023; called by muse, mutect2, varscan2
- ARID1A | c.1650dup p.Y551Lfs*72 | Frame Shift Ins (INS) | VAF 21/51 reads (41%) | catalogued as rs1415146710; called by mutect2, pindel, varscan2
- ATF7IP | c.3203del p.P1068Lfs*40 | Frame Shift Del (DEL) | VAF 7/30 reads (23%) | catalogued as rs1565549048; called by mutect2, varscan2
- BMP5 | c.331G>T p.G111W | Missense Mutation (SNP) | VAF 42/85 reads (49%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.746); catalogued as COSV100895982; called by muse, mutect2, varscan2
- BPI | c.603G>A p.M201I (on ENST00000262865; = p.M197I on NM_001725.3) | Missense Mutation (SNP) | VAF 16/36 reads (44%) | SIFT tolerated (0.23); PolyPhen benign (0.011); catalogued as COSV99480670; called by muse, mutect2, varscan2
- BPTF | c.6797C>T p.P2266L | Missense Mutation (SNP) | VAF 17/46 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1555671526, COSV100075028; called by muse, mutect2, varscan2
- CCDC190 | c.259G>A p.V87M | Missense Mutation (SNP) | VAF 6/116 reads (5%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as rs1311407331, COSV100905829; called by muse, mutect2
- CHD2 | c.2497C>T p.P833S | Missense Mutation (SNP) | VAF 4/27 reads (15%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.841); catalogued as COSV67708391; called by mutect2, varscan2
- CHD4 | c.1837C>T p.R613* (on ENST00000357008 / NM_001363606.2; = p.R626* on NM_001273.5) | Nonsense Mutation (SNP) | VAF 14/46 reads (30%) | catalogued as rs1374578320, COSV58911435; called by muse, mutect2, varscan2
- COL11A2 | c.149C>T p.A50V | Missense Mutation (SNP) | VAF 6/55 reads (11%) | SIFT tolerated (0.47); PolyPhen benign (0.167); catalogued as COSV100554066; called by muse, mutect2, varscan2
- COL22A1 | c.4783C>T p.L1595F | Missense Mutation (SNP) | VAF 13/36 reads (36%) | SIFT tolerated (0.36); PolyPhen benign (0.015); catalogued as rs561552719, COSV100278662; called by muse, mutect2, varscan2
- DENND4C | c.5141A>G p.N1714S (on ENST00000434457 / NM_001330640.2; = p.N1665S on NM_017925.7) | Missense Mutation (SNP) | VAF 12/28 reads (43%) | SIFT tolerated (0.93); PolyPhen benign (0.435); catalogued as COSV100727440; called by muse, mutect2, varscan2
- DHRS3 | c.481C>T p.R161C | Missense Mutation (SNP) | VAF 3/35 reads (9%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.973); catalogued as rs904973071, COSV100879633; called by muse, mutect2
- EGFL6 | c.565C>T p.R189* | Nonsense Mutation (SNP) | VAF 37/82 reads (45%) | catalogued as rs199619027, COSV100789878; called by muse, mutect2, varscan2
- FREM1 | c.3630G>T p.Q1210H | Missense Mutation (SNP) | VAF 37/80 reads (46%) | SIFT tolerated (0.08); PolyPhen benign (0.039); catalogued as COSV101084588, COSV66517884; called by muse, mutect2
- HCN1 | c.868G>T p.D290Y | Missense Mutation (SNP) | VAF 19/40 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV100299847, COSV100300383, COSV57517027; called by muse, mutect2, varscan2
- HGF | c.73G>A p.A25T | Missense Mutation (SNP) | VAF 15/39 reads (38%) | SIFT tolerated (0.7); PolyPhen benign (0); catalogued as COSV99737103; called by muse, mutect2, varscan2
- IGSF9 | c.2305C>T p.R769C (on ENST00000368094 / NM_001135050.2; = p.R753C on NM_020789.4) | Missense Mutation (SNP) | VAF 44/56 reads (79%) | SIFT deleterious (0.04); PolyPhen benign (0.249); catalogued as rs1262080229, COSV100829631; called by muse, mutect2, varscan2
- KMT2D | c.5357G>A p.R1786H | Missense Mutation (SNP) | VAF 6/37 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.869); catalogued as rs779659959, COSV99980722; called by muse, mutect2, varscan2
- LDHD | c.1189C>T p.R397W | Missense Mutation (SNP) | VAF 45/76 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs771516114, COSV100097115; called by muse, mutect2, varscan2
- LGSN | c.1267A>T p.T423S | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV101040539; called by mutect2, varscan2
- MIEF2 | c.70C>T p.L24F | Missense Mutation (SNP) | VAF 50/90 reads (56%) | SIFT deleterious (0.01); PolyPhen benign (0.164); catalogued as COSV100493662; called by muse, mutect2, varscan2
- MUC16 | c.1106C>T p.A369V | Missense Mutation (SNP) | VAF 22/39 reads (56%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.139); catalogued as rs1465303243, COSV67452845; called by muse, mutect2, varscan2
- MYOZ1 | c.655A>T p.K219* | Nonsense Mutation (SNP) | VAF 14/65 reads (22%) | catalogued as COSV100831864; called by muse, mutect2, varscan2
- NEK10 | c.1343G>C p.S448T | Missense Mutation (SNP) | VAF 26/46 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV100411898; called by muse, mutect2, varscan2
- NR2C2 | c.1496T>C p.V499A (on ENST00000393102; = p.V518A on NM_003298.5) | Missense Mutation (SNP) | VAF 26/56 reads (46%) | SIFT tolerated (0.13); PolyPhen benign (0.33); catalogued as COSV100038567; called by muse, mutect2, varscan2
- OR4M1 | c.33A>C p.E11D | Missense Mutation (SNP) | VAF 17/116 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.347); catalogued as COSV100271226; called by muse, mutect2, varscan2
- OTOA | c.109C>T p.Q37* | Nonsense Mutation (SNP) | VAF 22/64 reads (34%) | catalogued as COSV99624575; called by muse, mutect2, varscan2
- PCDH19 | c.592C>T p.R198C | Missense Mutation (SNP) | VAF 14/53 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99719897; called by muse, mutect2, varscan2
- PCIF1 | c.1967C>T p.T656M | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs150805893; called by muse, varscan2
- PIK3R3 | c.1094G>A p.R365Q | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV53110258, COSV99422002; called by muse, mutect2, varscan2
- PIWIL1 | c.172G>C p.G58R | Missense Mutation (SNP) | VAF 24/45 reads (53%) | SIFT tolerated (0.59); PolyPhen benign (0); catalogued as COSV99806440; called by muse, mutect2, varscan2
- PPP2R2D | c.1076C>T p.S359L | Missense Mutation (SNP) | VAF 26/80 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.094); catalogued as rs142846802, COSV70778739; called by muse, mutect2, varscan2
- PTGER3 | c.1207G>A p.V403M | Missense Mutation (SNP) | VAF 26/65 reads (40%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.157); catalogued as rs568020055, COSV100656960; called by muse, mutect2, varscan2
- ROBO1 | c.2540G>A p.R847Q | Missense Mutation (SNP) | VAF 22/49 reads (45%) | SIFT tolerated (0.58); PolyPhen benign (0.073); catalogued as rs1024115525, COSV101458748; called by muse, mutect2, varscan2
- SAYSD1 | c.415C>T p.R139* | Nonsense Mutation (SNP) | VAF 18/33 reads (55%) | catalogued as rs138955257; called by muse, varscan2
- SLIT1 | c.3941T>G p.I1314S | Missense Mutation (SNP) | VAF 35/115 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV99821462; called by muse, mutect2, varscan2
- STRADA | c.457G>A p.G153S (on ENST00000336174 / NM_001363786.1; = p.G116S on NM_153335.6) | Missense Mutation (SNP) | VAF 31/89 reads (35%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs768734514, COSV99834944; called by muse, mutect2, varscan2
- STXBP6 | c.256C>G p.R86G | Missense Mutation (SNP) | VAF 23/64 reads (36%) | SIFT tolerated (0.08); PolyPhen benign (0.001); catalogued as COSV100121844, COSV100122050; called by muse, mutect2, varscan2
- TTN | c.97448G>A p.S32483N (on ENST00000591111; = p.S25059N on NM_003319.4) | Missense Mutation (SNP) | VAF 29/58 reads (50%) | PolyPhen benign (0); catalogued as rs1271436308, COSV100614472; called by muse, mutect2, varscan2
- UBA1 | c.2865G>C p.W955C | Missense Mutation (SNP) | VAF 32/81 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100255730; called by muse, mutect2, varscan2
- ZNF560 | c.1690C>T p.R564* | Nonsense Mutation (SNP) | VAF 25/66 reads (38%) | catalogued as rs368814423; called by muse, mutect2, varscan2
- ZNF568 | c.125C>T p.T42I | Missense Mutation (SNP) | VAF 20/63 reads (32%) | SIFT tolerated (0.34); PolyPhen benign (0.015); catalogued as COSV100451288; called by muse, mutect2, varscan2
- ZNF780A | c.916G>A p.V306I | Missense Mutation (SNP) | VAF 32/76 reads (42%) | SIFT deleterious (0.04); PolyPhen benign (0.027); catalogued as COSV100575103; called by muse, mutect2, varscan2
- CHD4 | c.1368_1370del p.S457del (on ENST00000357008 / NM_001363606.2; = p.S470del on NM_001273.5) | In Frame Del (DEL) | VAF 22/58 reads (38%) | called by pindel, varscan2
- KMT2B | c.903_907del p.P302Cfs*30 | Frame Shift Del (DEL) | VAF 33/73 reads (45%) | called by mutect2, pindel, varscan2
- PTEN | c.413dup p.Y138* | Nonsense Mutation (INS) | VAF 66/137 reads (48%) | called by mutect2, pindel, varscan2
- PTEN | c.1003del p.R335Dfs*9 | Frame Shift Del (DEL) | VAF 17/59 reads (29%) | called by mutect2, pindel, varscan2
- TCF7L1 | c.1697_1708del p.L566_H569del | In Frame Del (DEL) | VAF 17/58 reads (29%) | called by mutect2, pindel, varscan2
- CARNS1 | c.1881C>T p.S627= | Silent (SNP) | VAF 15/44 reads (34%) | catalogued as rs751514911, COSV57050832; called by muse, mutect2, varscan2
- KIF14 | c.711G>A p.T237= | Silent (SNP) | VAF 21/110 reads (19%) | catalogued as rs772474712, COSV100950862; called by muse, mutect2, varscan2
- MELK | c.237C>G p.A79= | Silent (SNP) | VAF 8/39 reads (21%) | catalogued as COSV99974683; called by muse, mutect2, varscan2
- RASAL2 | c.1791G>A p.A597= | Silent (SNP) | VAF 22/110 reads (20%) | catalogued as rs775977356, COSV100862650; called by muse, mutect2, varscan2
- SEMA3A | c.1569G>A p.A523= | Silent (SNP) | VAF 9/20 reads (45%) | catalogued as rs770224463, COSV54869158; called by muse, mutect2, varscan2
- SRPK3 | c.780C>T p.T260= | Silent (SNP) | VAF 34/82 reads (41%) | catalogued as COSV99473189; called by muse, mutect2, varscan2
- TSR3 | c.624C>T p.C208= | Silent (SNP) | VAF 12/27 reads (44%) | catalogued as rs759381551, COSV50103908; called by muse, mutect2, varscan2
- WFS1 | c.1890C>T p.S630= | Silent (SNP) | VAF 17/41 reads (41%) | catalogued as COSV99901277; called by muse, mutect2, varscan2
- ATP11C | c.3298-760G>A | Intron (SNP) | VAF 13/36 reads (36%) | catalogued as rs1024672815, COSV100557971; called by muse, mutect2, varscan2
- EMC10 | c.679-234C>T | Intron (SNP) | VAF 29/49 reads (59%) | catalogued as COSV100618495; called by muse, mutect2, varscan2
- PLEC | c.524-5118C>T | Intron (SNP) | VAF 13/23 reads (57%) | catalogued as rs1554730555, COSV100514477; called by muse, mutect2, varscan2
